Surgical pathology report (de-identified scan), TCGA case TCGA-93-A4JP, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Washington University - St. Louis, specimen TCGA-93-A4JP-01A (Primary Tumor).

[page 1 of 4]
Surgical Pathology Report

Final

ICD-0-3
adenocarcinoma, papillary, NOS
8360/3
Site: lung, lower lobe C34.3

10/2/12

SURGICAL PATHOLOGY REPORT FINAL WITH ADDENDUM

Patient Name:

Address:

Gender:

DOB:

Service:

Cardiothoracic Surgery

Location:

MRN:

Hospital #:

Patient Type:

Accession #:

Taken:

Received:

Accessioned:

Reported:

Physician(s):

DIAGNOSIS:

LUNG, RIGHT MIDDLE/LOWER LOBES, WEDGE EXCISIONS - ADENOCARCINOMA

By this signature, I attest that the above diagnosis is based upon my personal examination of the slides (and/or other material indicated in the diagnosis).

***Report Electronically Reviewed and Signed Out By

Microscopic Description and Comment:

Sections of the right middle and lower lobes of the lung show moderately differentiated, papillary adenocarcinoma

History:

The patient is a year old man, of unstated race, with a left paratracheal lymph node positive for adenocarcinoma on fine needle aspiration. No clinical history is provided. Operative procedure: Wedge biopsies.

Specimen(s) Received:

A: LUNG, RIGHT MIDDLE LOBE NODULE
B: LUNG, RIGHT LOWER LOBE NODULE

Gross Description:

The specimens are received in two formalin-filled containers each labeled with the patient's name. The first container is labeled "right middle lobe nodule." It holds a portion of brown lung parenchyma and pleura measuring 1.5 x 1.0 x 0.7 cm. There is a firm irregular, white nodule present measuring 0.7 x 0.5 x 0.2 cm. Labeled A. Jar 0.

The second container is labeled "lower lobe right nodule." It holds a single portion of brown lung parenchyma with overlying pleura. There is a white, irregular, semi-firm nodule measuring 1.4 x 1.2 x 0.8 cm. Labeled B1 and B2. Jar 0.

[page 2 of 4]
SURGICAL PATHOLOGY REPORT

Addenda/Procedures

Addendum Ordered:
Addendum Complete:
Addendum Signed Out:

Status: Signed Out
By:

Addendum Comment

Fluorescence In-situ hybridization (FISH) Results:
Block A1

Negative FISH result for ALK gene rearrangement

nuc ish(ALKx5-8)[12]/(ALKx4)[15]/(ALKx3)[26]/(ALKx2)[42]

Comment: In this case, a gain of ALK was noted; 3-8 copies of ALK were observed in 53% of nuclei examined, the significance of which, if any, is unclear.

FISH for ALK-gene rearrangement at chromosomal locus 2p23 was performed utilizing FISH probe kit (IVD). The Vysis ALK Break Apart FISH Probe Kit® is a qualitative test to detect rearrangements involving the ALK gene via fluorescence in situ hybridization (FISH) in formalin-fixed paraffin-embedded (FFPE) non-small cell lung cancer (NSCLC) tissue specimens to aid in identifying those patients eligible for treatment with . The FISH laboratory follows the manufacturer's guidelines in the processing and analysis of this multiplexed IVD FISH probe.

Positive for gene rearrangement: ≥15% of a minimum of 100 interphase cells with positive signal pattern
Negative for gene rearrangement: <15% of a minimum of 100 interphase cells with positive signal pattern

Reference: Vysis ALK Break Apart FFPE FISH Probe Kit Package Insert

Addendum Ordered:
Addendum Complete:
Addendum Signed Out:

Status: Signed Out
By:

Addendum Comment
EGFR MUTATIONAL ANALYSIS

DATE RECEIVED:

GENPATH SPECIMEN ID NUMBER:

RESULTS
EGFR MUTATIONAL ANALYSIS: NONE DETECTED

INTERPRETIVE INFORMATION

The epidermal growth factor receptor (EGFR) is overexpressed in 40-80% of patients with non-small cell lung cancer (NSCLC). In

[page 3 of 4]
SURGICAL PATHOLOGY REPORT

patients who are unresponsive to standard chemotherapy, a subset respond to treatment with small molecule tyrosine kinase inhibitors (TKIs) of the EGFR intracellular domain, such as gefitinib (Iressa®) and erlotinib (Tarceva®). TKI therapy is more effective in patients who have never smoked, have adenocarcinoma histology, are female, and of Asian ethnicity. In the TKI responder group, up to 85% have somatic, heterozygous, activating gain-of-function mutations of EGFR.

Most EGFR mutations (80-90%) are in the tyrosine kinase coding domain in exons 18-21. The two most common sensitizing mutations are short in-frame deletions of exon 19 (45% of all mutations) and the L858R substitution in exon 21 (40-45% of all mutations). Another mutation, T790M in exon 20, has been shown to cause secondary resistance to gefitinib. In patients who develop resistance, approximately 43-50% acquire the T790M mutation. Altogether, EGFR mutations are seen in 10-20% of all patients.

This assay identifies all classical and unknown mutations in exon 19 and the L858R (totaling 85-90% of all EGFR mutations) as well as resistance mutation T790M. The lower limit of detection of this assay is 5% for exon 19 mutations, 1% for L858R, and 1% for T790M.

METHODOLOGY

Tumor DNA was extracted from paraffin-embedded tissue utilizing QIAmp Blood Kt and amplified by polymerase chain reaction (PCR). The EGFR mutation assay combines fluorescent PCR fragment analysis with allele-specific PCR for the detection of each of the 3 different mutations sites (exon 19, L858R, T790M) utilizing capillary electrophoresis with an ABI 3130 Genetic Analyzer.

REFERENCES

- Paez JG, Jänne PA, Lee JC, et al. EGFR Mutations in Lung Cancer: Correlation with Clinical Response to Gefitinib Therapy. *Science* 304:1497-1500, 2004.
- Mahesteran S, Sequist LV, Nagrath S, et al. Detection of Mutations in EGFR in Circulating Lung-Cancer Cells. *N Engl J Med* 359(4):366-377, 2008.
- Lynch TJ, Bell DW, Sordella R, et al. Activating Mutations in the Epidermal Growth Factor Receptor Underlying Responsiveness of Non-Small-Cell Lung Cancer to Gefitinib. *N Engl J Med* 350(21):2129-2139.
- Dacic S. EGFR Assays in Lung Cancer. *Adv Anat Pathol* 15(4):241-247.
- Zhang X, Chang A. Somatic mutations of the epidermal growth factor receptor and non-small-cell lung cancer. *J Med Genet* 44:166-172, 2007.
- Kancha RK, von Bubnoff N, Peschel C, et al. Functional Analysis of Epidermal Growth Factor Receptor (EGFR) Mutations and Potential Implications for EGFR Targeted Therapy. *Clin Cancer Res* 15(2):460-467, 2009.
- Pallis AG, Voutsina A, Kalikaki A, et al. 'Classical' but not 'other' mutations of EGFR kinase domain are associated with clinical outcome in gefitinib-treated patients with non-small cell lung cancer. *British Journal of Cancer* 97:1560-1566, 2007.
- Sharma S, Bell D, Settleman J, et al. Epidermal growth factor receptor mutations in lung cancer. *Nature Reviews/Cancer* 7:169-181, 2007.

This test was developed and its performance characteristics were determined by . It has not been cleared by the U.S. Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary. This test is used for clinical purposes. It should not be regarded as investigational or for research. This lab has been approved by CLIA 88 and designated as a high complexity laboratory and is qualified to perform this test.

[page 4 of 4]
SURGICAL PATHOLOGY REPORT

Surgical Pathology report is available on-line :

7/24/12

Source: NCI Genomic Data Commons file 41370f5e-912a-4e15-928a-17bcec3957c4 (TCGA-93-A4JP.3AFDF9A9-8D19-4060-86E0-B24AE8C83A82.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).